Somatic mutation profile of tumor specimen MMRF_1129_1_BM_CD138pos (aliquot MMRF_1129_1_BM_CD138pos_T2_TSE61_K03157) from MMRF case MMRF_1129, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.1 years (29,630 days).
Specimen MMRF_1129_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa542c66-c4f6-4ea4-ab53-7e186f1a37ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1129_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1129_1_PB_Whole_C1_TSE61_K03187; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/379726d6-7a47-4a88-bbb7-7439e6944e31

The open-access MAF lists 174 somatic variants for this specimen: 84 protein-altering or splice-affecting, 29 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, 3'UTR 43, Silent 29, 5'UTR 8, Intron 4, Frame Shift Ins 4, Nonsense Mutation 4, Frame Shift Del 3, RNA 3, 3'Flank 3, In Frame Del 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASB10 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs866384832, COSV99318291; called by muse, mutect2, varscan2
- COQ8A | c.296C>G p.P99R | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV64657326; called by muse, mutect2, varscan2
- DDI2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs200176580; called by muse, mutect2, varscan2
- DDX20 | c.2362_2364del p.Y788del | In Frame Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs767587043; called by pindel, varscan2
- DIS3 | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372878316; called by muse, mutect2
- FAM167A | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs148222965; called by muse, mutect2, varscan2
- FAM78B | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 86/138 reads (62%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.49); catalogued as rs759808562, COSV57978754; called by muse, mutect2, varscan2
- GPR68 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 47/49 reads (96%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs914155634, COSV53175437; called by muse, mutect2, varscan2
- KCNT2 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.666); catalogued as COSV99651977; called by muse, mutect2
- KRTAP1-1 | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 174/351 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1315150500; called by muse, mutect2
- MYH3 | c.1775C>G p.S592* | Nonsense Mutation (SNP) | VAF 18/178 reads (10%) | catalogued as COSV99878027; called by muse, mutect2
- OR7E24 | c.42G>T p.R14S | Missense Mutation (SNP) | VAF 236/448 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs200395125; called by muse, mutect2, varscan2
- PLEC | c.6580G>A p.A2194T (on ENST00000322810 / NM_201380.4; = p.A2084T on NM_000445.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs542184546, COSV59613632; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A2 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239056908; called by muse, mutect2, varscan2
- SYCP1 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs570746669; called by muse, mutect2, varscan2
- TTN | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | PolyPhen benign (0.009); catalogued as COSV100588611; called by muse, mutect2, varscan2
- UGT2B7 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.238); catalogued as rs964197344; called by muse, mutect2, varscan2
- VSIG4 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.284); catalogued as COSV66074262; called by muse, mutect2, varscan2
- ACRBP | c.1258G>C p.V420L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACTL9 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ALDH8A1 | c.1148A>G p.D383G | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ATP1A3 | c.548T>C p.V183A (on ENST00000545399 / NM_001256214.2; = p.V170A on NM_152296.5) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BOC | c.2472_2485del p.L826Afs*5 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- CASP10 | c.1295C>T p.A432V (on ENST00000272879 / NM_032974.5; = p.A389V on NM_001230.5) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLIC1 | c.341T>G p.F114C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CNOT1 | c.4389G>T p.M1463I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- COL12A1 | c.6218_6223del p.V2073_P2074del | In Frame Del (DEL) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- COL4A2 | c.3902C>A p.P1301Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- CSF1R | c.2445C>A p.A815= | Splice Region (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- DIS3 | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELAVL3 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EPHA6 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FAM120C | c.1751T>C p.L584P | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- FAM83H | c.2638G>T p.G880W | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- FKBP6 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FOXA3 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FREM1 | c.1645G>C p.D549H | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAK | c.2788C>T p.L930F | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- GSDMB | c.901C>G p.L301V (on ENST00000418519 / NM_001165958.1; = p.L279V on NM_018530.2) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- H4C9 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 215/506 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- HIRIP3 | c.293C>G p.S98* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- INTS9 | c.1961T>A p.F654Y | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- KCNC3 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 57/358 reads (16%) | called by muse, mutect2, varscan2
- KCNN2 | c.1052T>G p.L351W (on ENST00000264773; = p.L563W on NM_021614.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL21 | c.171del p.S58Afs*44 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- LENG8 | c.2239A>G p.T747A | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- LRRTM3 | c.1516T>A p.S506T | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGI1 | c.4175C>T p.P1392L | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MCMDC2 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDGA2 | c.2568T>A p.N856K (on ENST00000399232 / NM_001113498.2; = p.N558K on NM_182830.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MFAP3 | c.812_816del p.I271Rfs*15 | Frame Shift Del (DEL) | VAF 31/150 reads (21%) | called by mutect2, pindel, varscan2
- MSRB2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH11 | c.2072A>G p.D691G | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- MYH14 | c.4252G>T p.A1418S | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- NCDN | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NCOR1 | c.466C>G p.P156A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- NDUFB10 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NFKBIB | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOMO3 | c.965C>G p.P322R | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NRG2 | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- NUDT12 | c.411C>A p.D137E | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.011); called by muse, mutect2
- OCA2 | c.1187T>C p.I396T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- OR1A1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.887); called by muse, mutect2
- PITX3 | c.669dup p.G224Rfs*38 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | called by mutect2, varscan2
- PPP6R3 | c.1864dup p.I622Nfs*25 (on ENST00000393800 / NM_001352375.2; = p.I542Nfs*25 on NM_018312.5) | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- REC114 | c.40A>C p.T14P | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- REPS1 | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2
- SEC14L4 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- STOX2 | c.977A>C p.N326T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SULT1C3 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYNJ2 | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2
- TAF1L | c.3499G>T p.D1167Y | Missense Mutation (SNP) | VAF 53/508 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- TCAIM | c.-42A>G | Splice Region (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- TCTE1 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 74/77 reads (96%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TNS3 | c.600dup p.L201Sfs*55 | Frame Shift Ins (INS) | VAF 18/122 reads (15%) | called by mutect2, pindel, varscan2
- TOP2B | c.4321dup p.S1441Kfs*20 (on ENST00000264331 / NM_001330700.2; = p.S1436Kfs*20 on NM_001068.3) | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- TTN | c.419A>T p.D140V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- USP15 | c.1616A>G p.N539S (on ENST00000280377 / NM_001351159.2; = p.N510S on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- VSIG4 | c.497A>C p.Q166P | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- XCR1 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.163); called by muse, mutect2
- ZNF208 | c.1365T>A p.C455* | Nonsense Mutation (SNP) | VAF 284/752 reads (38%) | called by muse, varscan2
- ZNF407 | c.1334A>G p.N445S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ACSBG2 | c.813C>T p.L271= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99397159; called by muse, mutect2
- ADCY1 | c.780C>T p.N260= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs777067499; called by muse, mutect2, varscan2
- ADRA1D | c.954G>A p.A318= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs61759841, COSV101062907; called by muse, mutect2, varscan2
- APLNR | c.867C>T p.N289= | Silent (SNP) | VAF 134/412 reads (33%) | called by muse, mutect2, varscan2
- ATP10A | c.1719C>T p.I573= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as rs540055667; called by muse, mutect2, varscan2
- CFD | c.541C>A p.R181= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs762667527; called by muse, mutect2
- CLEC14A | c.663G>A p.P221= | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- ENO3 | c.435C>G p.L145= | Silent (SNP) | VAF 27/295 reads (9%) | called by muse, mutect2
- FAT4 | c.7050C>T p.I2350= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- FNDC4 | c.370C>A p.R124= | Silent (SNP) | VAF 72/152 reads (47%) | catalogued as COSV53022015; called by muse, mutect2, varscan2
- GPR32 | c.348C>A p.L116= | Silent (SNP) | VAF 50/253 reads (20%) | called by muse, mutect2, varscan2
- GRIN2A | c.3708C>T p.C1236= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs780909404, COSV58023313, COSV58047100; called by muse, mutect2, varscan2
- MAST1 | c.699C>A p.T233= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as rs1325977785; called by muse, mutect2, varscan2
- MICAL3 | c.2808C>A p.S936= | Silent (SNP) | VAF 16/31 reads (52%) | called by mutect2, varscan2
- MINDY2 | c.1641G>A p.K547= | Silent (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- OR5D14 | c.346T>C p.L116= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV59456317; called by muse, mutect2, varscan2
- OR8J3 | c.564T>G p.S188= | Silent (SNP) | VAF 73/197 reads (37%) | catalogued as COSV56882180; called by muse, mutect2, varscan2
- OSR1 | c.756A>G p.L252= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs1558359244; called by muse, mutect2, varscan2
- PELI2 | c.639C>T p.V213= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs763468065; called by muse, mutect2, varscan2
- PLXNB2 | c.1740C>T p.I580= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1380564488; called by muse, mutect2, varscan2
- PPP1R36 | c.993C>G p.V331= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100072942; called by mutect2, varscan2
- RECK | c.1806T>G p.S602= | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2
- RNF123 | c.2730C>T p.D910= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as rs754283760; called by muse, mutect2
- RYR2 | c.12333C>T p.N4111= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs748716535; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETD9 | c.519G>A p.P173= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs146080809; called by muse, mutect2, varscan2
- SLC25A13 | c.1929A>C p.A643= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- SRRM1 | c.621C>T p.S207= | Silent (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- TSHZ3 | c.441C>T p.N147= | Silent (SNP) | VAF 80/144 reads (56%) | catalogued as rs530960780, COSV99550288; called by muse, mutect2, varscan2
- USP34 | c.5052G>C p.G1684= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1468171692; called by muse, mutect2, varscan2
- AC018638.4 | n.648G>A | RNA (SNP) | VAF 60/1367 reads (4%) | catalogued as rs1274272151; called by muse, mutect2
- AL021937.6 | chr22:32367700 G>A | 3'Flank (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- ALOX15B | c.*185G>C | 3'UTR (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- ANGPT1 | c.*1096T>G | 3'UTR (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- ANK1 | c.*348C>T | 3'UTR (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- ANP32A | c.*1471G>C | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- AP1M1 | c.*450G>T | 3'UTR (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- ARAP2 | c.*1164C>T | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- CAPS | c.*427G>C | 3'UTR (SNP) | VAF 24/43 reads (56%) | catalogued as rs1394063238; called by muse, mutect2, varscan2
- CNTFR | c.*165C>A | 3'UTR (SNP) | VAF 12/184 reads (7%) | catalogued as rs1053610296; called by muse, mutect2
- COL22A1 | c.*198A>T | 3'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, varscan2
- COL22A1 | c.*138T>C | 3'UTR (SNP) | VAF 22/41 reads (54%) | called by muse, varscan2
- CYTH4 | c.*1091T>C | 3'UTR (SNP) | VAF 61/110 reads (55%) | called by muse, mutect2, varscan2
- DDX6 | c.*3175G>T | 3'UTR (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- DEPDC1 | c.-11C>G | 5'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- EIF4EBP2 | c.*5342C>T | 3'UTR (SNP) | VAF 24/122 reads (20%) | catalogued as rs544444729; called by muse, mutect2, varscan2
- FAM234A | chr16:269199 C>T | 3'Flank (SNP) | VAF 18/223 reads (8%) | catalogued as rs527708863; called by muse, mutect2
- GABRA4 | c.*1789T>C | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- GABRG1 | c.*4773G>T | 3'UTR (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- GALNT15 | c.*1289A>C | 3'UTR (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- GBF1 | c.-132C>T | 5'UTR (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- GNA12 | c.*2072C>T | 3'UTR (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- GPR107 | c.*330G>T | 3'UTR (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- ID1 | c.*249A>G | 3'UTR (SNP) | VAF 29/61 reads (48%) | catalogued as rs1043717480; called by muse, mutect2, varscan2
- IER2 | c.*302_*304del | 3'UTR (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel
- IGFN1 | c.1242-1817A>G | Intron (SNP) | VAF 248/1035 reads (24%) | called by muse, mutect2, varscan2
- KCNE3 | c.*2354G>A | 3'UTR (SNP) | VAF 23/39 reads (59%) | catalogued as rs1034215014; called by muse, mutect2, varscan2
- KCNIP4 | c.61+99322T>C | Intron (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- KIF24 | c.*1506G>C | 3'UTR (SNP) | VAF 37/290 reads (13%) | called by muse, mutect2, varscan2
- KITLG | c.*1066C>A | 3'UTR (SNP) | VAF 49/118 reads (42%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10694A>T | Intron (SNP) | VAF 63/150 reads (42%) | called by muse, mutect2, varscan2
- MCM10 | chr10:13210880 G>A | 3'Flank (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- MED26 | c.*412C>T | 3'UTR (SNP) | VAF 15/87 reads (17%) | catalogued as rs1022955807; called by muse, mutect2, varscan2
- MED26 | c.*411A>T | 3'UTR (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- MROH2B | c.-42T>A | 5'UTR (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- NKG7 | c.*102C>G | 3'UTR (SNP) | VAF 25/71 reads (35%) | catalogued as COSV52467528; called by muse, mutect2, varscan2
- OTUD3 | c.*1355T>C | 3'UTR (SNP) | VAF 42/74 reads (57%) | called by muse, mutect2, varscan2
- OXSR1 | c.-267T>C | 5'UTR (SNP) | VAF 18/38 reads (47%) | catalogued as rs1235555318; called by muse, mutect2, varscan2
- PCDH11X | n.492C>A | RNA (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- PDE4B | c.*576T>A | 3'UTR (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- PELO | c.*664T>A | 3'UTR (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.*777C>G | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.*10C>T | 3'UTR (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- RAVER2 | c.*2074G>T | 3'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- RSPO4 | c.*616C>G | 3'UTR (SNP) | VAF 9/69 reads (13%) | called by muse, varscan2
- RSPO4 | c.*599T>G | 3'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, varscan2
- RWDD4 | c.-52T>G | 5'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- SGK3 | c.*1060C>T | 3'UTR (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- SLC43A2 | c.*689C>G | 3'UTR (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- SMPD4BP | n.2500G>A | RNA (SNP) | VAF 8/164 reads (5%) | catalogued as rs1157755928; called by muse, mutect2
- SPECC1L | c.-90T>C | 5'UTR (SNP) | VAF 4/47 reads (9%) | catalogued as rs1385042574; called by muse, mutect2
- SRD5A1 | c.*737T>A | 3'UTR (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- TFAP2C | c.*682A>G | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- TP53I11 | c.*618_*623del | 3'UTR (DEL) | VAF 113/222 reads (51%) | called by mutect2, pindel, varscan2
- USP6 | c.-1561C>G | 5'UTR (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- WDR44 | c.-207G>A | 5'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- WEE1 | c.*458A>T | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- XKR4 | c.1007-71281G>T | Intron (SNP) | VAF 21/614 reads (3%) | called by muse, mutect2
- YAF2 | c.*1502A>G | 3'UTR (SNP) | VAF 3/21 reads (14%) | catalogued as rs940784684; called by muse, mutect2
- ZNF579 | c.*36C>T | 3'UTR (SNP) | VAF 42/224 reads (19%) | called by muse, mutect2, varscan2
- ZNF740 | c.*952A>T | 3'UTR (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
